Somatic mutation profile of tumor specimen 0D9OOM from CCDI case PBBIEL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.8 years (5,053 days).
Specimen 0D9OOM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e57e991-bbb9-4770-9c3d-0e1992c9ba9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D92H5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a04d55ff-d5f8-4eab-8579-cc1b75045058

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 181/691 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GOLGA3 | c.2858A>G p.N953S | Missense Mutation (SNP) | VAF 72/782 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs370767206; called by muse, mutect2
- IL13RA1 | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); called by mutect2, varscan2
- H1-7 | c.282C>T p.S94= | Silent (SNP) | VAF 102/508 reads (20%) | catalogued as rs1470554571, COSV100622259; called by muse, mutect2, varscan2
- SEMG2 | c.675C>T p.D225= | Silent (SNP) | VAF 104/432 reads (24%) | catalogued as rs374623110; called by muse, mutect2, varscan2
